Somatic mutation profile of tumor specimen TCGA-HC-A6HY-01A (aliquot TCGA-HC-A6HY-01A-11D-A31L-08) from TCGA case TCGA-HC-A6HY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 51.4 years (18,779 days).
Specimen TCGA-HC-A6HY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30c03920-b578-4a5d-ac63-9551a22879ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A6HY-10A (Blood Derived Normal), aliquot TCGA-HC-A6HY-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66f3e618-6255-46ea-9187-521272713e6f

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 2, RNA 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.6346G>A p.A2116T | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.184); catalogued as rs747312001, COSV61363835; called by muse, mutect2, varscan2
- AFF2 | c.3781G>T p.D1261Y | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV53996155, COSV54007286; called by muse, mutect2, varscan2
- AHNAK2 | c.2324G>A p.G775D | Missense Mutation (SNP) | VAF 97/287 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60920774; called by muse, mutect2, varscan2
- CLEC4A | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs375140919; called by muse, mutect2, varscan2
- CRTC1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs762670352, COSV58720486; called by muse, mutect2, varscan2
- CTR9 | c.3096-1G>C p.X1032_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | catalogued as COSV63728975; called by muse, mutect2, varscan2
- GABRG1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs940269899, COSV54951321; called by muse, mutect2, varscan2
- GDE1 | c.596A>G p.N199S | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62059688; called by muse, mutect2, varscan2
- KLC4 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765504507, COSV52435237; called by muse, mutect2, varscan2
- KLHL30 | c.247G>C p.V83L | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.146); catalogued as COSV59976925; called by muse, mutect2, varscan2
- LRRC7 | c.2587C>T p.Q863* (on ENST00000651989 / NM_001370785.2; = p.Q830* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as COSV50501456; called by muse, mutect2, varscan2
- MROH2B | c.1631A>G p.K544R | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.127); catalogued as COSV68186151; called by muse, mutect2
- MUC16 | c.18136T>C p.S6046P | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV67477237; called by muse, mutect2, varscan2
- OR4S1 | c.727A>T p.I243F | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV60679364; called by muse, mutect2, varscan2
- OR5B2 | c.375C>A p.C125* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as COSV56908624, COSV56908827; called by muse, mutect2, varscan2
- SNX17 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV52008730; called by muse, mutect2, varscan2
- TTN | c.10244C>T p.T3415M (on ENST00000591111; = p.T3369M on NM_003319.4) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | PolyPhen possibly damaging (0.59); catalogued as rs761799688, COSV100614536, COSV60169373; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO3A | c.3574del p.M1192* | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, varscan2
- CHST3 | c.522C>T p.F174= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV64151239; called by muse, mutect2, varscan2
- OR51I1 | c.51A>T p.T17= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV66508413; called by muse, mutect2, varscan2
- RAG2 | c.492T>C p.S164= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as COSV57558455; called by muse, mutect2, varscan2
- RFXANK | c.576G>A p.T192= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as rs895628840, COSV57393118; called by muse, mutect2, varscan2
- DCHS2 | n.328G>A | RNA (SNP) | VAF 30/94 reads (32%) | catalogued as rs571144811, COSV59729731; called by muse, mutect2, varscan2
